Somatic mutation profile of tumor specimen TCGA-EL-A3N2-01A (aliquot TCGA-EL-A3N2-01A-11D-A20C-08) from TCGA case TCGA-EL-A3N2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.6 years (8,989 days).
Specimen TCGA-EL-A3N2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f44eeb16-e4c4-4b1a-a01b-55ae64dcb28d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3N2-11A (Solid Tissue Normal), aliquot TCGA-EL-A3N2-11A-11D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f8c5c6b-dbb3-44f3-b92b-d346829e6e12

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA2D3 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV55546323; called by muse, mutect2, varscan2
- CBX6 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV53321060; called by muse, mutect2, varscan2
- FBXO10 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52833471; called by muse, mutect2, varscan2
- KCNA7 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV55503609; called by muse, mutect2
- NLRP5 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as rs370513314; called by muse, mutect2, varscan2
- NXF3 | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.449); catalogued as COSV67703928; called by muse, mutect2, varscan2
- SRPX2 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 131/361 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs146063801, COSV65933772, COSV65933811; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407823 C>T | 5'Flank (SNP) | VAF 38/85 reads (45%) | catalogued as COSV56679052; called by muse, mutect2, varscan2
